Gene-level copy-number profile of tumor specimen TARGET-40-0A4I4M-01A from TARGET case TARGET-40-0A4I4M, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.9 years (6,916 days).
Specimen TARGET-40-0A4I4M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.267bb02c-9059-5065-ac9b-3484881331a6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I4M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 379 have no estimate.
https://portal.gdc.cancer.gov/files/5700dcdd-ab96-4db9-ae5a-a8b32f8eaf67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 4,341; copy number 2: 24,650; copy number 3: 13,196; copy number 4: 12,330; copy number 5: 3,047; copy number 6: 1,226; copy number 7: 620; copy number 8: 5; copy number 9: 24; copy number 10: 27; copy number 11: 43; copy number 12: 68; copy number 14: 11; copy number 15: 3; copy number 16: 63; copy number 17: 7; copy number 18: 41; copy number 24: 12.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,723,581, 5 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1.
- chr15:24,162,754–24,343,464, 4 genes: PWRN2, AC087463.1, AC087463.2, AC087463.3.
- chr19:2,100,988–2,164,468, 1 gene (within-gene range 0–2): AP3D1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,520 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,484,403–19,819,502, 10 genes, copy number 7 (within-gene range 3–7): MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6, TMCO4, RNF186, AL391883.1.
- chr1:62,597,520–64,192,685, 43 genes, copy number 5: ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1, AL162400.2, AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1.
- chr1:65,576,129–97,995,000, 480 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:111,680,630–116,166,241, 99 genes, copy number 5 (broad region; genes not listed).
- chr1:152,759,561–157,417,259, 267 genes, copy number 5–10 (within-gene range 5–11) (broad region; genes not listed).
- chr1:177,923,956–178,921,841, 21 genes, copy number 5: SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1.
- chr1:183,613,537–190,480,735, 89 genes, copy number 5–6 (broad region; genes not listed).
- chr1:206,470,476–212,699,840, 152 genes, copy number 5–12 (broad region; genes not listed).
- chr1:213,731,416–215,237,090, 19 genes, copy number 5–17 (within-gene range 3–17): AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775, SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2.
- chr1:225,803,148–225,999,343, 12 genes, copy number 24: AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2.
- chr1:226,493,188–228,858,556, 103 genes, copy number 5 (broad region; genes not listed).
- chr1:231,475,956–235,161,283, 75 genes, copy number 5–18 (broad region; genes not listed).
- chr2:77,652,025–80,648,861, 28 genes, copy number 5–6 (within-gene range 4–6): AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1.
- chr2:88,857,161–100,426,107, 292 genes, copy number 5 (broad region; genes not listed).
- chr2:100,739,958–101,475,112, 16 genes, copy number 5 (within-gene range 2–5): AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8.
- chr4:17,552,117–19,098,740, 13 genes, copy number 9: NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63, AC093898.1, AC093871.1, AC006840.1.
- chr5:32,103,445–33,368,778, 24 genes, copy number 5: AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1.
- chr6:70,216,040–72,599,634, 39 genes, copy number 6–12: COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1.
- chr6:73,593,379–74,734,319, 11 genes, copy number 6 (within-gene range 4–6): SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2.
- chr7:5,306,790–5,970,683, 21 genes, copy number 5 (within-gene range 2–5): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B.
- chr7:7,255,154–7,718,607, 8 genes, copy number 14: AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3.
- chr7:32,580,949–33,109,404, 19 genes, copy number 12 (within-gene range 3–12): DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9.
- chr7:34,124,948–35,038,271, 11 genes, copy number 5: AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N.
- chr7:57,402,181–68,319,676, 237 genes, copy number 6 (broad region; genes not listed).
- chr8:42,101,318–53,959,303, 169 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:91,909,738–96,431,160, 96 genes, copy number 6 (broad region; genes not listed).
- chr10:4,024,903–5,185,187, 22 genes, copy number 6 (within-gene range 4–6): AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P.
- chr14:40,267,283–44,386,064, 26 genes, copy number 5 (within-gene range 3–5): AL049828.2, AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1.
- chr16:33,687,025–35,085,060, 43 genes, copy number 11: BMS1P8, AC136428.4, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2, BCLAF1P2, FP325313.1, FP325313.3, FP325313.2, AC135776.4, AC135776.5, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr17:7,839,904–27,708,138, 591 genes, copy number 6–7 (broad region; genes not listed).
- chr17:32,830,219–36,726,346, 154 genes, copy number 5 (broad region; genes not listed).
- chr17:49,834,239–50,215,922, 26 genes, copy number 6: AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4.
- chr17:69,961,568–72,237,203, 24 genes, copy number 5: LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.
- chr17:77,198,950–83,095,122, 253 genes, copy number 5–6 (broad region; genes not listed).
- chr19:27,638,483–29,841,818, 52 genes, copy number 7–16: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr19:31,797,666–40,348,527, 394 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr20:8,929,895–16,983,033, 97 genes, copy number 5–6 (broad region; genes not listed).
- chr20:17,887,363–31,311,962, 250 genes, copy number 5 (broad region; genes not listed).
- chr20:63,337,339–64,313,132, 63 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–19,345,312, 124 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
